Gene-level copy-number profile of tumor specimen TCGA-AA-3854-01A from TCGA case TCGA-AA-3854, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Mucinous adenocarcinoma; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage I; Age at diagnosis: 71.2 years (26,022 days).
Specimen TCGA-AA-3854-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-COAD.5512f091-a4d8-4fb5-9b8a-e885c141e17b.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-AA-3854-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 812 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/0700dae9-43e6-4a5e-81b0-c198f7639185

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 679; copy number 2: 53,360; copy number 3: 5,127; copy number 4: 265; copy number 5: 1; copy number 6: 130; copy number 7: 129; copy number 8: 46; copy number 12: 21; copy number 13: 1; copy number 17: 52.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-AA-3854-01A-01D-0903-01): tumor purity 0.88, ploidy 2.09, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 380 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:33,440,696–45,895,970, 204 genes, copy number 5–17 (broad region; genes not listed).
- chr7:142,636,924–142,779,537, 18 genes, copy number 6: TRBV21-1, TRBV22-1, TRBV23-1, TRBV24-1, MTRNR2L6, TRBV25-1, TRBVA, TRBV26, TRBVB, TRBV27, TRBV28, PGBD4P1, AC244472.1, TRBV29-1, PRSS1, PRSS2, PRSS3P1, WBP1LP1.
- chr17:58,982,638–63,819,317, 158 genes, copy number 6–8 (within-gene range 2–8) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 679. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
